Somatic mutation profile of tumor specimen CPT000814 (aliquot CPT000814-0010) from CPTAC case 604, project CPTAC-2 (Breast). Sex at birth: female; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 41.0 years (14,964 days).
Specimen CPT000814: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5941d56c-8afe-4d4b-b636-c419b8870869.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CPT000820 (Blood Derived Normal), aliquot CPT000820-0002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09acaa84-fbfd-4fc9-ba07-32aa538d8661

The open-access MAF lists 100 somatic variants for this specimen: 66 protein-altering or splice-affecting, 16 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 16, Intron 11, Nonsense Mutation 6, Frame Shift Del 5, Translation Start Site 2, 3'UTR 2, 5'UTR 2, RNA 2, 5'Flank 1, Nonstop Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG8 | c.1978G>C p.V660L | Missense Mutation (SNP) | VAF 138/544 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772542948; called by muse, mutect2, varscan2
- ADA | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 100/531 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs921477673, COSV65740290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP1B3 | c.164C>G p.S55* | Nonsense Mutation (SNP) | VAF 59/190 reads (31%) | catalogued as COSV53950279, COSV53950402; called by muse, mutect2, varscan2
- BMP4 | c.1011C>A p.C337* | Nonsense Mutation (SNP) | VAF 166/465 reads (36%) | catalogued as COSV55416451; called by muse, mutect2, varscan2
- C12orf71 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV70282779; called by muse, mutect2, varscan2
- CCDC39 | c.1855C>T p.Q619* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV56487464; called by muse, mutect2
- CDH11 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51767655; called by muse, mutect2, varscan2
- CDKL2 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as rs753616785, COSV56734141; called by muse, mutect2, varscan2
- DENND5A | c.3253T>C p.S1085P | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100063855; called by muse, mutect2, varscan2
- ELL2 | c.885G>C p.Q295H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV52983579; called by muse, mutect2, varscan2
- FOXA2 | c.781C>G p.L261V (on ENST00000377115 / NM_153675.3; = p.L267V on NM_021784.5) | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV101008232; called by muse, mutect2, varscan2
- GMPS | c.472G>C p.D158H | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV55810386; called by muse, mutect2
- IFT88 | c.767G>T p.R256I (on ENST00000319980 / NM_001318493.2; = p.R247I on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as rs1474573713, COSV60672929; called by muse, mutect2, varscan2
- IGSF9B | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.671); catalogued as rs1468741985, COSV58069416; called by muse, mutect2, varscan2
- ITIH6 | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54486882; called by muse, mutect2, varscan2
- KIFC2 | c.1837C>T p.P613S | Missense Mutation (SNP) | VAF 71/397 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.095); catalogued as rs757007735, COSV56762796, COSV56763278; called by muse, mutect2, varscan2
- KMO | c.1359G>C p.L453F | Missense Mutation (SNP) | VAF 50/210 reads (24%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV100086923; called by muse, mutect2, varscan2
- LRRC37A2 | c.4241C>G p.S1414C | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs759662818; called by muse, mutect2
- LRRIQ1 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV67829639; called by muse, mutect2, varscan2
- MAGEC1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 93/255 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV53571941; called by muse, mutect2, varscan2
- MGMT | c.528C>A p.C176* (on ENST00000306010; = p.C145* on NM_002412.5) | Nonsense Mutation (SNP) | VAF 96/198 reads (48%) | catalogued as COSV60030080; called by muse, mutect2, varscan2
- NIBAN3 | c.2051C>T p.S684F | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); catalogued as rs1166159915, COSV53110061; called by muse, mutect2, varscan2
- NIF3L1 | c.1051C>T p.R351* (on ENST00000409020 / NM_001369444.1; = p.R324* on NM_021824.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 16/257 reads (6%) | catalogued as rs994390127; called by muse, mutect2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 99/233 reads (42%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- OR6P1 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 68/766 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV58110569; called by muse, mutect2
- PAPPA | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 95/348 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs774728290, COSV60283021; called by muse, mutect2, varscan2
- PIKFYVE | c.2459-2A>T p.X820_splice | Splice Site (SNP) | VAF 74/246 reads (30%) | catalogued as COSV100009530; called by muse, mutect2, varscan2
- PRSS35 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 71/271 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1157353385, COSV63800795; called by muse, mutect2, varscan2
- PRUNE1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV54958805; called by muse, mutect2, varscan2
- SEC14L2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.807); catalogued as rs760486237, COSV100464856; called by muse, mutect2, varscan2
- SEMA6C | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 74/564 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1395556119; called by muse, mutect2, varscan2
- SLC28A3 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.028); catalogued as COSV66152298, COSV66153954; called by muse, mutect2, varscan2
- SLTM | c.507A>T p.E169D | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV51055403; called by muse, mutect2, varscan2
- SPTA1 | c.6462G>T p.K2154N | Missense Mutation (SNP) | VAF 768/1147 reads (67%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV63755888; called by muse, mutect2, varscan2
- SSTR4 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as rs959639186; called by muse, mutect2, varscan2
- SYDE1 | c.1404C>G p.I468M | Missense Mutation (SNP) | VAF 86/180 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54620698; called by muse, mutect2, varscan2
- SZT2 | c.8439G>C p.K2813N (on ENST00000634258 / NM_001365999.1; = p.K2756N on NM_015284.4) | Missense Mutation (SNP) | VAF 86/317 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV65171309; called by muse, mutect2, varscan2
- TENM4 | c.5105G>A p.R1702H | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs756075933, COSV53642633; called by muse, mutect2, varscan2
- THBS4 | c.1690G>A p.D564N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63469976; called by muse, mutect2, varscan2
- TNN | c.2155G>C p.V719L | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV53432620, COSV99510881; called by muse, mutect2
- TP53 | c.610del p.E204Sfs*43 | Frame Shift Del (DEL) | VAF 337/575 reads (59%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by mutect2, pindel, varscan2
- TRAPPC13 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV51556571; called by muse, mutect2, varscan2
- TRIQK | c.5G>A p.G2D | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758550065, COSV66649837; called by muse, mutect2
- TTYH1 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 174/240 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100002270, COSV56612986; called by muse, mutect2, varscan2
- YY1AP1 | c.513G>C p.Q171H (on ENST00000295566 / NM_139118.2; = p.Q94H on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/585 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV55121061; called by muse, mutect2, varscan2
- ZCCHC2 | c.2704C>G p.L902V | Missense Mutation (SNP) | VAF 282/368 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV54039325; called by muse, mutect2, varscan2
- ZNF689 | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as COSV54909343; called by muse, mutect2, varscan2
- ZNF77 | c.1429C>G p.Q477E | Missense Mutation (SNP) | VAF 56/158 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV58821672, COSV58822222; called by mutect2, varscan2
- ACTRT1 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- AHCTF1 | c.3112del p.I1038Sfs*9 (on ENST00000366508; = p.I1012Sfs*9 on NM_015446.5) | Frame Shift Del (DEL) | VAF 25/92 reads (27%) | called by mutect2, pindel, varscan2
- AOC1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- CPNE8 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.081); called by muse, varscan2
- EPDR1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 119/164 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- JCAD | c.2210C>A p.P737H | Missense Mutation (SNP) | VAF 13/377 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- KHSRP | c.1775C>G p.P592R | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.242); called by muse, mutect2
- MEPCE | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- MYO6 | c.685C>G p.L229V | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NFE2L2 | c.1818G>C p.*606Yext*2 | Nonstop Mutation (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- PIK3R2 | c.816G>A p.G272= | Splice Region (SNP) | VAF 47/235 reads (20%) | called by muse, mutect2, varscan2
- PTGER3 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 131/449 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA4C | c.1420del p.S474Afs*28 | Frame Shift Del (DEL) | VAF 164/321 reads (51%) | called by mutect2, pindel, varscan2
- SLC23A1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC44A2 | c.1299_1318del p.E435Pfs*118 | Frame Shift Del (DEL) | VAF 62/250 reads (25%) | called by mutect2, pindel, varscan2
- SMYD3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/103 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ZNF213 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 24/394 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2
- ZNF33A | c.1559G>A p.G520E (on ENST00000458705 / NM_006974.3; = p.G521E on NM_006954.2) | Missense Mutation (SNP) | VAF 21/460 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ANGPTL4 | c.1023C>T p.C341= | Silent (SNP) | VAF 77/241 reads (32%) | catalogued as rs1399302322, COSV100035328; called by muse, mutect2, varscan2
- BICD1 | c.2775G>A p.Q925= | Silent (SNP) | VAF 39/227 reads (17%) | catalogued as COSV55682190; called by muse, mutect2, varscan2
- CARD14 | c.1629C>T p.V543= | Silent (SNP) | VAF 73/270 reads (27%) | catalogued as COSV60124714; called by muse, mutect2, varscan2
- CDC20B | c.552C>G p.L184= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV57051624; called by muse, mutect2, varscan2
- CP | c.570C>G p.A190= | Silent (SNP) | VAF 20/648 reads (3%) | catalogued as rs1444875443; called by muse, mutect2
- EXPH5 | c.5070G>A p.Q1690= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as rs1287373545, COSV56204415; called by muse, mutect2, varscan2
- HFM1 | c.399C>T p.G133= | Silent (SNP) | VAF 52/114 reads (46%) | catalogued as COSV99645137; called by muse, mutect2
- IRF8 | c.1206C>G p.V402= | Silent (SNP) | VAF 143/530 reads (27%) | catalogued as COSV51898776; called by muse, mutect2, varscan2
- KLHL30 | c.333G>A p.A111= | Silent (SNP) | VAF 66/295 reads (22%) | catalogued as rs748799375, COSV59979089; called by muse, mutect2, varscan2
- OR4C12 | c.597G>A p.V199= | Silent (SNP) | VAF 141/263 reads (54%) | catalogued as COSV58860416; called by muse, mutect2, varscan2
- PARP3 | c.402G>A p.K134= | Silent (SNP) | VAF 46/220 reads (21%) | catalogued as rs779675204; called by mutect2, varscan2
- PPP1R9A | c.2043A>G p.K681= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV56899153; called by muse, mutect2, varscan2
- SLC51A | c.655C>T p.L219= | Silent (SNP) | VAF 34/122 reads (28%) | called by muse, varscan2
- SPIDR | c.1956G>T p.T652= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV52381430; called by mutect2, varscan2
- TNN | c.2157G>A p.V719= | Silent (SNP) | VAF 39/218 reads (18%) | catalogued as COSV99510883; called by muse, mutect2
- WDR81 | c.4983C>T p.D1661= (on ENST00000409644 / NM_001163809.2; = p.D610= on NM_152348.4) | Silent (SNP) | VAF 101/252 reads (40%) | called by muse, mutect2, varscan2
- AGBL4 | c.634+48986T>G | Intron (SNP) | VAF 35/150 reads (23%) | called by muse, mutect2, varscan2
- ASL | c.656-36C>T | Intron (SNP) | VAF 122/346 reads (35%) | called by muse, mutect2, varscan2
- CLASRP | c.1707+25del | Intron (DEL) | VAF 61/179 reads (34%) | called by mutect2, pindel, varscan2
- DPY19L2P2 | n.423C>G | RNA (SNP) | VAF 120/172 reads (70%) | called by muse, mutect2, varscan2
- EFEMP1 | c.81+30C>T | Intron (SNP) | VAF 75/274 reads (27%) | catalogued as rs1311240991; called by muse, mutect2, varscan2
- FAM193B | c.1275+961C>T | Intron (SNP) | VAF 60/166 reads (36%) | catalogued as rs779317855; called by muse, mutect2, varscan2
- GDI2 | c.1137-14C>G | Intron (SNP) | VAF 12/380 reads (3%) | called by muse, mutect2
- GPALPP1 | c.-3C>A | 5'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- GVINP1 | n.3966G>C | RNA (SNP) | VAF 127/375 reads (34%) | called by muse, mutect2, varscan2
- MRPL35 | c.*2980G>T | 3'UTR (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- PAX4 | c.*29_*30del | 3'UTR (DEL) | VAF 207/383 reads (54%) | called by pindel, varscan2
- PLPP5 | c.463+39C>A | Intron (SNP) | VAF 334/795 reads (42%) | called by muse, mutect2, varscan2
- PNKD | c.237-16519C>T | Intron (SNP) | VAF 61/105 reads (58%) | catalogued as rs1461115674; called by muse, mutect2, varscan2
- SERTAD4 | c.-18+738G>C | Intron (SNP) | VAF 40/226 reads (18%) | called by muse, mutect2, varscan2
- SLC22A20P | n.1081+2075G>A | Intron (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- UBP1 | c.-11G>A | 5'UTR (SNP) | VAF 62/113 reads (55%) | catalogued as rs762275556, COSV99372438; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866904 C>G | 5'Flank (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- ZNF497 | c.-111-995G>A | Intron (SNP) | VAF 54/108 reads (50%) | catalogued as rs1568560429; called by muse, mutect2, varscan2
